Somatic mutation profile of tumor specimen C3N-02160-04 (aliquot CPT0213960006) from CPTAC case C3N-02160, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-02160-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edf0da98-d236-41d4-a17f-a172ea4a636f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02160-71 (Blood Derived Normal), aliquot CPT0214050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1695440b-58b4-4c31-a922-ab1cec07a30f

The open-access MAF lists 114 somatic variants for this specimen: 80 protein-altering or splice-affecting, 22 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 22, Intron 7, Nonsense Mutation 6, 3'UTR 5, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNA | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 108/200 reads (54%) | catalogued as rs398123614, COSV100774508; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67988626; called by muse, mutect2, varscan2
- CHD8 | c.2873G>C p.C958S (on ENST00000646647 / NM_001170629.2; = p.C679S on NM_020920.4) | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV67870198; called by muse, mutect2, varscan2
- CLDND2 | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1254335351; called by muse, mutect2, varscan2
- COL12A1 | c.6080G>T p.G2027V | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59394345; called by muse, mutect2, varscan2
- FHDC1 | c.3001A>G p.K1001E | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52603933; called by muse, mutect2, varscan2
- FSTL5 | c.2041G>A p.G681S | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766085810, COSV60182251; called by muse, mutect2, varscan2
- HLA-DOA | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.861); catalogued as rs200187983, COSV57715079; called by muse, mutect2, varscan2
- KCNQ2 | c.1771C>T p.Q591* (on ENST00000359125 / NM_172107.4; = p.Q563* on NM_004518.6) | Nonsense Mutation (SNP) | VAF 89/385 reads (23%) | catalogued as COSV100609221; called by muse, mutect2, varscan2
- LAMA1 | c.4807-2A>T p.X1603_splice | Splice Site (SNP) | VAF 61/246 reads (25%) | catalogued as COSV104432633; called by muse, mutect2, varscan2
- MUC12 | c.14063A>G p.K4688R (on ENST00000379442; = p.K4545R on NM_001164462.1) | Missense Mutation (SNP) | VAF 3/219 reads (1%) | SIFT tolerated (0.08); catalogued as rs1250276125, COSV65184420; called by muse, mutect2
- PCDHB13 | c.226T>A p.L76M | Missense Mutation (SNP) | VAF 57/510 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99506665; called by muse, mutect2, varscan2
- POTEI | c.182T>A p.M61K | Missense Mutation (SNP) | VAF 157/705 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs755034697; called by muse, mutect2, varscan2
- SIX1 | c.245A>T p.K82I | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV55959506; called by muse, mutect2, varscan2
- SLC6A19 | c.1704G>C p.E568D | Missense Mutation (SNP) | VAF 127/563 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as COSV57251429; called by muse, mutect2, varscan2
- SLC9C2 | c.2228A>G p.Y743C | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335053133; called by muse, mutect2, varscan2
- SRBD1 | c.2830G>T p.G944W | Missense Mutation (SNP) | VAF 75/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558545770; called by muse, mutect2, varscan2
- TMCO3 | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1296195527; called by muse, mutect2, varscan2
- TPGS1 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs541802856; called by muse, mutect2, varscan2
- ZSCAN5A | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs1190390490, COSV99570745; called by muse, mutect2, varscan2
- ABCA4 | c.3916C>T p.P1306S | Missense Mutation (SNP) | VAF 93/352 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.1477A>G p.K493E | Missense Mutation (SNP) | VAF 19/489 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- ADAMTS13 | c.1165A>T p.S389C | Missense Mutation (SNP) | VAF 146/437 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ADAMTS16 | c.2849_2851del p.R950del | In Frame Del (DEL) | VAF 24/124 reads (19%) | called by pindel, varscan2
- BRD2 | c.452A>T p.N151I | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASKIN2 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP350 | c.7997A>T p.N2666I | Missense Mutation (SNP) | VAF 94/289 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIAPIN1 | c.698_699insC p.A234Gfs*14 | Frame Shift Ins (INS) | VAF 35/198 reads (18%) | called by mutect2, pindel, varscan2
- CXCL6 | c.275T>A p.L92Q | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP7B1 | c.1255A>T p.I419L | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2
- DISP2 | c.3745A>T p.R1249W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- DPYS | c.505A>T p.M169L | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- FAT3 | c.2272A>T p.N758Y | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN2 | c.7841-2A>T p.X2614_splice | Splice Site (SNP) | VAF 113/484 reads (23%) | called by muse, mutect2, varscan2
- GCKR | c.429-2A>T p.X143_splice | Splice Site (SNP) | VAF 92/321 reads (29%) | called by muse, mutect2, varscan2
- GOLGB1 | c.8815A>T p.R2939W | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- GRK2 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GSTCD | c.746A>T p.Q249L (on ENST00000360505 / NM_001031720.3; = p.Q162L on NM_024751.3) | Missense Mutation (SNP) | VAF 136/514 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSDL1 | c.760A>T p.S254C | Missense Mutation (SNP) | VAF 95/423 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- IL26 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIAA1109 | c.347A>T p.Q116L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KIR2DL1 | c.100del p.H34Tfs*6 | Frame Shift Del (DEL) | VAF 45/475 reads (9%) | called by mutect2, pindel, varscan2
- KMT2D | c.10953A>T p.Q3651H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KRTAP10-1 | c.736_745del p.M246Pfs*79 | Frame Shift Del (DEL) | VAF 57/307 reads (19%) | called by mutect2, pindel, varscan2
- LIG4 | c.1898A>T p.K633M | Missense Mutation (SNP) | VAF 95/395 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LONRF2 | c.1357A>T p.M453L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- MAGEC2 | c.1029A>T p.R343S | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- MGAT4A | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- MYBPC1 | c.247G>A p.A83T (on ENST00000550270 / NM_206820.2; = p.A108T on NM_002465.4) | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCDN | c.589del p.A197Hfs*77 | Frame Shift Del (DEL) | VAF 71/320 reads (22%) | called by mutect2, pindel, varscan2
- NT5C1B | c.512T>A p.L171Q (on ENST00000359846 / NM_001199086.2; = p.L111Q on NM_033253.4) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- NUTM2G | c.89T>G p.F30C | Missense Mutation (SNP) | VAF 123/386 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PAPPA2 | c.1265A>T p.H422L | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDE1C | c.2000A>T p.Y667F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4A | c.2174A>T p.Q725L (on ENST00000380702 / NM_001111307.2; = p.Q486L on NM_006202.3) | Missense Mutation (SNP) | VAF 94/427 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGLYRP3 | c.23T>A p.L8H | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLR1A | c.2597A>T p.K866M | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POP4 | c.324G>T p.Q108H | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- POTEG | c.1093A>T p.M365L | Missense Mutation (SNP) | VAF 56/752 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.047); called by muse, mutect2
- PRKG1 | c.1582A>T p.K528* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- RASGEF1C | c.26A>T p.D9V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, varscan2
- RTN4IP1 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SCT | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SDHA | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, varscan2
- SETD3 | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SH3BGR | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SIGLEC10 | c.1783C>A p.L595M | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC27A4 | c.760A>T p.K254* | Nonsense Mutation (SNP) | VAF 51/165 reads (31%) | called by muse, mutect2, varscan2
- SLC38A1 | c.1389_1390dup p.L464Cfs*66 | Frame Shift Ins (INS) | VAF 55/242 reads (23%) | called by mutect2, pindel, varscan2
- STING1 | c.500A>T p.Y167F | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- STRC | c.3334A>T p.T1112S | Missense Mutation (SNP) | VAF 79/510 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.037); called by muse, varscan2
- TDRD7 | c.2921A>G p.H974R | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TPTE | c.877A>G p.K293E (on ENST00000618007 / NM_199261.4; = p.K275E on NM_199259.4) | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2
- TRPC7 | c.1518C>G p.H506Q | Missense Mutation (SNP) | VAF 78/398 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- TTC39A | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- XIRP2 | c.9377T>A p.V3126E (on ENST00000628543; = p.V3301E on NM_152381.6) | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- YTHDF2 | c.403G>T p.G135* | Nonsense Mutation (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- YTHDF2 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZEB2 | c.3097A>T p.K1033* | Nonsense Mutation (SNP) | VAF 141/501 reads (28%) | called by muse, mutect2, varscan2
- ZEB2 | c.814dup p.M272Nfs*8 | Frame Shift Ins (INS) | VAF 96/420 reads (23%) | called by mutect2, pindel, varscan2
- ABCC9 | c.321A>T p.P107= | Silent (SNP) | VAF 95/391 reads (24%) | called by muse, mutect2, varscan2
- AGBL2 | c.702A>T p.I234= | Silent (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
- C1orf162 | c.69A>T p.P23= | Silent (SNP) | VAF 80/410 reads (20%) | called by muse, mutect2, varscan2
- CDC123 | c.159A>T p.P53= | Silent (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- CELSR1 | c.7476G>T p.L2492= | Silent (SNP) | VAF 147/598 reads (25%) | called by muse, mutect2, varscan2
- CLEC4F | c.669C>T p.N223= | Silent (SNP) | VAF 39/189 reads (21%) | called by muse, mutect2, varscan2
- CTAGE9 | c.963T>A p.A321= | Silent (SNP) | VAF 132/588 reads (22%) | catalogued as COSV100020517; called by muse, mutect2, varscan2
- DPPA5 | c.36G>A p.P12= | Silent (SNP) | VAF 55/246 reads (22%) | called by muse, mutect2, varscan2
- DRD1 | c.735A>T p.T245= | Silent (SNP) | VAF 42/189 reads (22%) | called by muse, mutect2, varscan2
- EDRF1 | c.2931A>T p.L977= (on ENST00000356792 / NM_001202438.2; = p.L943= on NM_015608.2) | Silent (SNP) | VAF 67/313 reads (21%) | called by muse, mutect2, varscan2
- GML | c.415C>T p.L139= | Silent (SNP) | VAF 27/216 reads (13%) | called by muse, mutect2, varscan2
- HRH2 | c.216G>T p.L72= | Silent (SNP) | VAF 26/327 reads (8%) | catalogued as rs1384787309; called by muse, mutect2
- IPO9 | c.33C>T p.S11= | Silent (SNP) | VAF 52/187 reads (28%) | called by muse, mutect2, varscan2
- LILRB5 | c.1323G>A p.Q441= (on ENST00000449561 / NM_001081442.3; = p.Q440= on NM_006840.5) | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs1424492346; called by muse, mutect2, varscan2
- LRRK1 | c.1989C>T p.A663= | Silent (SNP) | VAF 69/230 reads (30%) | called by muse, mutect2, varscan2
- MYH15 | c.4638A>G p.E1546= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as rs564636419; called by muse, mutect2, varscan2
- NINL | c.2638A>C p.R880= | Silent (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1071T>A p.A357= | Silent (SNP) | VAF 35/195 reads (18%) | called by muse, mutect2, varscan2
- RIMS1 | c.3411C>G p.S1137= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- RP1 | c.4884T>A p.V1628= | Silent (SNP) | VAF 78/280 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.8262T>A p.A2754= (on ENST00000591111; = p.A2708= on NM_003319.4) | Silent (SNP) | VAF 56/299 reads (19%) | called by muse, mutect2, varscan2
- ZFR | c.2829A>T p.P943= | Silent (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- ABCA8 | c.2916+38T>A | Intron (SNP) | VAF 38/175 reads (22%) | called by muse, mutect2, varscan2
- ADM2 | c.*141G>A | 3'UTR (SNP) | VAF 111/427 reads (26%) | called by muse, mutect2, varscan2
- CCM2 | c.*249C>T | 3'UTR (SNP) | VAF 44/160 reads (28%) | called by muse, mutect2, varscan2
- CEP128 | c.1209+869A>G | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs1445806624; called by muse, mutect2, varscan2
- DDX41 | c.*814A>T | 3'UTR (SNP) | VAF 51/318 reads (16%) | called by muse, mutect2, varscan2
- EPS15 | c.561+2409del | Intron (DEL) | VAF 27/105 reads (26%) | called by mutect2, pindel, varscan2
- KIR3DX1 | n.1183-10A>T | Intron (SNP) | VAF 79/299 reads (26%) | called by muse, mutect2, varscan2
- LYST | c.192+54A>T | Intron (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2
- PNKD | c.237-16544C>A | Intron (SNP) | VAF 88/240 reads (37%) | called by muse, mutect2, varscan2
- SLC35A3 | c.*683G>A | 3'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- VNN3 | c.*10G>T | 3'UTR (SNP) | VAF 8/71 reads (11%) | catalogued as rs751864562; called by muse, varscan2
- ZNF717 | c.184+55A>T | Intron (SNP) | VAF 64/247 reads (26%) | called by muse, mutect2, varscan2
